Somatic mutation profile of tumor specimen TCGA-EJ-7783-01A (aliquot TCGA-EJ-7783-01A-11D-2114-08) from TCGA case TCGA-EJ-7783, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.1 years (25,600 days).
Specimen TCGA-EJ-7783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc729af5-708d-4f34-b507-f1fbdcb47a31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7783-10A (Blood Derived Normal), aliquot TCGA-EJ-7783-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b526003-b112-4c48-8a4f-84c1fee32266

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 22, Silent 10, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.10240G>A p.A3414T | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.141); catalogued as rs367666935; called by muse, mutect2, varscan2
- ADAMTS19 | c.3131C>A p.T1044N | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV50801883; called by muse, mutect2, varscan2
- ATM | c.1452del p.W484* | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as COSV53738852; called by mutect2, pindel, varscan2
- BCL6 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1231829175, COSV51655975; called by muse, mutect2
- CELSR2 | c.4054A>G p.K1352E | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as COSV54779806; called by muse, mutect2, varscan2
- CSDE1 | c.2176C>T p.R726C (on ENST00000358528 / NM_001007553.3; = p.R695C on NM_007158.6) | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV54758524; called by muse, mutect2
- CTC1 | c.1292T>G p.L431R | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV59855634; called by muse, varscan2
- DHTKD1 | c.2036T>G p.F679C | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV53807525; called by muse, mutect2
- FAF1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.14); catalogued as rs370452298, COSV65644381; called by muse, mutect2, varscan2
- FAT3 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53090140, COSV53178008; called by muse, mutect2, varscan2
- GAST | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 53/475 reads (11%) | catalogued as rs782557458, COSV61475484; called by muse, mutect2, varscan2
- MAP2K4 | c.962T>A p.V321E | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62260928; called by muse, mutect2, varscan2
- PCDH9 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60586985; called by muse, mutect2, varscan2
- PCDHA6 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65358259; called by muse, mutect2
- PCDHB4 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as rs1425672587, COSV52024729; called by muse, mutect2
- PRSS58 | c.531T>A p.N177K | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV73488877; called by muse, mutect2
- SEPHS2 | c.470A>T p.N157I | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs376948016, COSV72100830; called by muse, mutect2, varscan2
- SLC22A4 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV52360433; called by muse, mutect2, varscan2
- SULF2 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs140635355; called by muse, mutect2, varscan2
- SYT1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs868227414, COSV54050678; called by muse, mutect2, varscan2
- TBX20 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV68786042; called by muse, mutect2
- TMEM192 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV60586379; called by muse, mutect2, varscan2
- TRIM31 | c.1093T>G p.S365A | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.206); catalogued as COSV65060251; called by muse, mutect2
- TXNL1 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV54181187; called by muse, mutect2, varscan2
- AHDC1 | c.3813G>A p.P1271= | Silent (SNP) | VAF 34/153 reads (22%) | catalogued as rs376593773; called by muse, mutect2, varscan2
- EIF5 | c.1275C>T p.D425= | Silent (SNP) | VAF 8/111 reads (7%) | catalogued as COSV53686925; called by muse, mutect2
- FAM187B | c.696C>T p.L232= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs914780937, COSV61201812; called by muse, mutect2, varscan2
- ISLR | c.675G>A p.P225= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs554846282, COSV51435498; called by muse, mutect2, varscan2
- KIAA1614 | c.75A>G p.T25= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV62553850; called by muse, mutect2, varscan2
- MAP3K5 | c.1308G>T p.A436= | Silent (SNP) | VAF 31/167 reads (19%) | catalogued as COSV62892450; called by muse, mutect2, varscan2
- PRKCG | c.759C>T p.N253= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs751772455, COSV54726550; called by muse, mutect2, varscan2
- SH3PXD2A | c.3288G>T p.V1096= (on ENST00000369774 / NM_001365079.1; = p.V1068= on NM_014631.2) | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV60120907; called by muse, mutect2, varscan2
- TCOF1 | c.1626G>A p.E542= (on ENST00000377797 / NM_001135243.1; = p.E465= on NM_000356.4) | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs750136296, COSV60346626; called by muse, mutect2, varscan2
- TTC37 | c.2823G>A p.L941= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV62457047; called by muse, mutect2, varscan2
